Gene-level copy-number profile of tumor specimen C3L-08164-01 from CPTAC case C3L-08164, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 56.6 years (20,679 days).
Specimen C3L-08164-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb590e47-abc3-4270-94f1-d7066bb9f8da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08164-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/c3d365f7-fb34-4f2f-87d3-89ff383d04b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 26,208; copy number 2: 30,202; copy number 3: 1,163; copy number 4: 551; copy number 5: 190; copy number 6: 1; copy number 7: 60; copy number 8: 16; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–2): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 268 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:36,521,721–36,626,138, 2 genes, copy number 6–12: NAMPTP1, Y_RNA.
- chr17:142,789–2,025,334, 62 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:38,925,168–40,093,867, 51 genes, copy number 5 (within-gene range 4–5): LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA.
- chr20:41,684,986–46,864,104, 153 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23,865. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
